Somatic mutation profile of tumor specimen ALCH-B4N9-TTP1-A (aliquot ALCH-B4N9-TTP1-A-1-0-D-A81V-36) from ALCHEMIST case ALCH-B4N9, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 63.4 years (23,166 days).
Specimen ALCH-B4N9-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 00e1c6fb-3a53-4791-9f1a-0117d4959b23.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4N9-NB1-A (Blood Derived Normal), aliquot ALCH-B4N9-NB1-A-1-0-D-A81V-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26399681-15de-44f4-a9d7-a5e72850ddb8

The open-access MAF lists 458 somatic variants for this specimen: 322 protein-altering or splice-affecting, 86 silent, 50 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 281, Silent 86, Intron 27, Nonsense Mutation 17, Splice Site 8, 3'UTR 7, Frame Shift Del 7, RNA 6, 5'UTR 6, Frame Shift Ins 5, 5'Flank 3, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.2359C>T p.R787* | Nonsense Mutation (SNP) | VAF 125/261 reads (48%) | hotspot (GDC flag); catalogued as rs137853293, CM900196, COSV57296164; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC10 | c.3461G>A p.R1154Q (on ENST00000372530 / NM_001198934.2; = p.R1126Q on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 124/270 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs375025499; called by muse, mutect2, varscan2
- ABCC2 | c.2242G>A p.G748R | Missense Mutation (SNP) | VAF 67/236 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as rs762263251; called by muse, mutect2, varscan2
- ABCC9 | c.2871A>C p.E957D | Missense Mutation (SNP) | VAF 45/323 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV53979676; called by muse, mutect2, varscan2
- ABLIM1 | c.2303G>T p.R768L | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs775966839; called by muse, mutect2, varscan2
- ACACA | c.5098A>C p.K1700Q | Missense Mutation (SNP) | VAF 106/330 reads (32%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.657); catalogued as rs949371213; called by muse, mutect2, varscan2
- AHNAK2 | c.17047C>A p.P5683T | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as rs758053805; called by muse, mutect2
- ASPM | c.3936G>T p.L1312F | Missense Mutation (SNP) | VAF 125/490 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.358); catalogued as rs1260401433; called by muse, mutect2, varscan2
- BCAN | c.1252A>C p.S418R | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs759487112; called by muse, mutect2, varscan2
- CABIN1 | c.5182C>T p.L1728F | Missense Mutation (SNP) | VAF 75/345 reads (22%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.255); catalogued as rs753426877; called by muse, mutect2, varscan2
- CACNA1A | c.2729G>T p.R910L | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.09); catalogued as COSV64205556; called by muse, mutect2, varscan2
- CACNA1B | c.6310C>A p.R2104S | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.603); catalogued as COSV53143470; called by muse, mutect2, varscan2
- CACNA1I | c.5567_5569del p.F1856del | In Frame Del (DEL) | VAF 48/219 reads (22%) | catalogued as rs774891224; called by mutect2, pindel, varscan2
- CCDC33 | c.274G>T p.D92Y | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs1247002491, COSV58348692; called by muse, mutect2, varscan2
- CDH12 | c.1675C>A p.R559S | Missense Mutation (SNP) | VAF 53/289 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs372690961, COSV66392476; called by muse, mutect2, varscan2
- CFAP20DC | c.2237G>A p.R746Q (on ENST00000482387 / NM_001351530.2; = p.R495Q on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 83/374 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs372630966; called by muse, mutect2, varscan2
- CFHR3 | c.252C>A p.L84= | Splice Region (SNP) | VAF 128/439 reads (29%) | catalogued as COSV66402164; called by muse, mutect2, varscan2
- COL13A1 | c.1861G>C p.D621H (on ENST00000398978 / NM_001130103.2; = p.D549H on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/195 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100637731; called by muse, mutect2, varscan2
- COL18A1 | c.349G>T p.V117L | Missense Mutation (SNP) | VAF 205/579 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.958); catalogued as COSV62700182; called by muse, mutect2, varscan2
- COL5A1 | c.997G>A p.V333I | Missense Mutation (SNP) | VAF 61/595 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs762624092; called by muse, mutect2, varscan2
- CSMD1 | c.659C>A p.S220Y | Missense Mutation (SNP) | VAF 73/221 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.238); catalogued as rs150247043; called by muse, mutect2, varscan2
- CSPG5 | c.1276G>T p.V426L | Missense Mutation (SNP) | VAF 137/287 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); catalogued as rs760452015, COSV53129794; called by muse, mutect2, varscan2
- CTSW | c.1001G>A p.G334E | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370386652, COSV100327198; called by muse, mutect2
- CYP7A1 | c.694C>T p.H232Y | Missense Mutation (SNP) | VAF 50/492 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs746711199; called by muse, mutect2, varscan2
- DBN1 | c.1226C>T p.A409V | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs369597152; called by muse, mutect2, varscan2
- DNAH14 | c.1252C>T p.R418C (on ENST00000445597; = p.R399C on NM_001145154.3) | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs777899897; called by muse, mutect2, varscan2
- DST | c.11210G>A p.C3737Y (on ENST00000361203 / NM_001374722.1; = p.C1325Y on NM_015548.5) | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT tolerated (0.82); PolyPhen benign (0.054); catalogued as rs1179281392, COSV55029300; called by muse, mutect2
- DUOX2 | c.977C>T p.P326L | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.523); catalogued as rs1224220219, COSV59908509; called by muse, mutect2, varscan2
- DUSP12 | c.595C>T p.Q199* | Nonsense Mutation (SNP) | VAF 11/168 reads (7%) | catalogued as rs770024507; called by muse, mutect2
- ETV5 | c.1009G>T p.D337Y | Missense Mutation (SNP) | VAF 102/233 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); catalogued as COSV60501719; called by muse, mutect2, varscan2
- EVC2 | c.2686G>A p.V896M | Missense Mutation (SNP) | VAF 34/520 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs761177898, COSV60394104; called by muse, mutect2
- FBXO8 | c.758T>G p.L253R | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV101183781; called by muse, mutect2, varscan2
- FLNC | c.6149G>T p.G2050V | Missense Mutation (SNP) | VAF 58/357 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57953231; called by muse, mutect2, varscan2
- FRAS1 | c.3865C>T p.L1289F | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as rs767587376; called by muse, mutect2, varscan2
- FREM1 | c.1273C>A p.L425I | Missense Mutation (SNP) | VAF 14/276 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as COSV63087305; called by muse, mutect2
- GAB4 | c.655C>T p.Q219* | Nonsense Mutation (SNP) | VAF 30/117 reads (26%) | catalogued as rs763795980; called by muse, mutect2, varscan2
- GBP7 | c.383A>G p.Y128C | Missense Mutation (SNP) | VAF 24/320 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748554081, COSV54009611; called by muse, mutect2
- GNAI1 | c.865G>T p.E289* | Nonsense Mutation (SNP) | VAF 25/190 reads (13%) | catalogued as COSV63522486; called by muse, mutect2, varscan2
- GP6 | c.905G>T p.G302V | Missense Mutation (SNP) | VAF 44/201 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59978755; called by muse, mutect2, varscan2
- GRN | c.836-1G>T p.X279_splice | Splice Site (SNP) | VAF 73/508 reads (14%) | catalogued as CS064419, CS128891; called by muse, mutect2, varscan2
- GTPBP2 | c.992G>A p.R331H | Missense Mutation (SNP) | VAF 176/446 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.397); catalogued as rs956751637, COSV61077277; called by muse, mutect2, varscan2
- GZMH | c.124C>A p.Q42K | Missense Mutation (SNP) | VAF 18/253 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53539020; called by muse, mutect2
- HAPLN3 | c.218G>T p.R73L | Missense Mutation (SNP) | VAF 27/235 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as COSV62084471; called by muse, mutect2, varscan2
- HCRTR1 | c.841C>A p.R281S | Missense Mutation (SNP) | VAF 83/319 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101036334; called by muse, mutect2, varscan2
- HNF4G | c.1101G>T p.Q367H (on ENST00000354370 / NM_001330561.2; = p.Q414H on NM_004133.5) | Missense Mutation (SNP) | VAF 64/164 reads (39%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); catalogued as COSV62968009; called by muse, mutect2, varscan2
- IFNA16 | c.513C>G p.I171M | Missense Mutation (SNP) | VAF 66/333 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.975); catalogued as COSV66510411; called by muse, mutect2, varscan2
- IGSF11 | c.646G>C p.V216L (on ENST00000393775 / NM_001015887.3; = p.V215L on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 191/417 reads (46%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.62); catalogued as COSV100677254; called by muse, mutect2, varscan2
- ITGAD | c.1883C>A p.P628H | Missense Mutation (SNP) | VAF 63/219 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66758324; called by muse, mutect2, varscan2
- KCNH7 | c.1613C>A p.A538D | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV59807325; called by muse, mutect2
- KIRREL1 | c.1153G>A p.V385M | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63285074; called by muse, mutect2, varscan2
- LAMC3 | c.4375C>T p.R1459W | Missense Mutation (SNP) | VAF 40/518 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1411067036; called by muse, mutect2
- LRRC32 | c.1166G>A p.R389Q | Missense Mutation (SNP) | VAF 65/199 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0.013); catalogued as rs754104595, COSV52632492; called by muse, mutect2, varscan2
- MARCHF11 | c.806C>A p.P269H | Missense Mutation (SNP) | VAF 145/466 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60127505; called by muse, mutect2, varscan2
- MEGF8 | c.6017G>C p.R2006P (on ENST00000251268 / NM_001271938.2; = p.R1939P on NM_001410.3) | Missense Mutation (SNP) | VAF 168/444 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.345); catalogued as COSV52091182; called by muse, mutect2, varscan2
- MEIOC | c.2788G>T p.E930* | Nonsense Mutation (SNP) | VAF 31/310 reads (10%) | catalogued as COSV59518991; called by muse, mutect2, varscan2
- MFSD13A | c.1366G>T p.A456S | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as COSV53269899; called by muse, mutect2, varscan2
- MTO1 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771594943, COSV64773294; called by muse, mutect2, varscan2
- MYO7A | c.5625G>C p.Q1875H | Missense Mutation (SNP) | VAF 27/184 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1031559000; called by muse, mutect2, varscan2
- NF1 | c.4066G>T p.E1356* | Nonsense Mutation (SNP) | VAF 159/481 reads (33%) | catalogued as CD141502, CM096912; called by muse, mutect2, varscan2
- NF1 | c.5184dup p.A1729Cfs*28 (on ENST00000358273 / NM_001042492.3; = p.A1708Cfs*28 on NM_000267.3) | Frame Shift Ins (INS) | VAF 6/52 reads (12%) | catalogued as CI086456; called by mutect2, varscan2
- NLRP4 | c.2489C>A p.A830D | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs762532051, COSV56707174; called by muse, mutect2, varscan2
- NPC1L1 | c.1978G>T p.V660L | Missense Mutation (SNP) | VAF 183/467 reads (39%) | SIFT tolerated (0.79); PolyPhen benign (0.006); catalogued as COSV56927203; called by muse, mutect2, varscan2
- NT5DC4 | c.25C>T p.R9C | Missense Mutation (SNP) | VAF 132/309 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs866705625; called by muse, mutect2, varscan2
- OR4A47 | c.572A>G p.H191R | Missense Mutation (SNP) | VAF 64/171 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs758533393; called by muse, mutect2, varscan2
- OR4K5 | c.500C>A p.P167H | Missense Mutation (SNP) | VAF 37/512 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100262206, COSV60005266; called by muse, mutect2
- OR5AR1 | c.355G>T p.A119S | Missense Mutation (SNP) | VAF 71/208 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV100265762, COSV57255333; called by muse, mutect2, varscan2
- OR5H15 | c.903C>A p.F301L | Missense Mutation (SNP) | VAF 125/230 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62948980; called by muse, mutect2, varscan2
- OR8H3 | c.655G>T p.V219L | Missense Mutation (SNP) | VAF 57/248 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0.019); catalogued as COSV57910577, COSV57911785; called by muse, mutect2, varscan2
- PAPPA | c.2492A>G p.Q831R | Missense Mutation (SNP) | VAF 17/174 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.585); catalogued as COSV60277907; called by muse, mutect2, varscan2
- PAX3 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 22/357 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as CM973770, COSV60588705; called by muse, mutect2
- PHEX | c.1105A>T p.R369* | Nonsense Mutation (SNP) | VAF 123/327 reads (38%) | catalogued as CM117103; called by muse, mutect2, varscan2
- PNPLA6 | c.1538C>T p.A513V (on ENST00000414982 / NM_001166111.2; = p.A465V on NM_006702.5) | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.009); catalogued as COSV99652847; called by muse, mutect2, varscan2
- POMT2 | c.2176G>T p.G726W | Missense Mutation (SNP) | VAF 122/392 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM074455; called by muse, mutect2, varscan2
- RALGDS | c.1871G>T p.G624V | Missense Mutation (SNP) | VAF 127/614 reads (21%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as rs1463707240; called by muse, mutect2, varscan2
- SACS | c.12407T>G p.L4136R | Missense Mutation (SNP) | VAF 46/474 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV66534211, COSV66534777; called by muse, mutect2
- SDK2 | c.1871G>T p.R624L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.159); catalogued as rs147076298, COSV66184246; called by muse, mutect2
- SETBP1 | c.2831G>A p.S944N | Missense Mutation (SNP) | VAF 125/532 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as COSV56333564; called by muse, mutect2, varscan2
- SETD1B | c.4625G>A p.G1542E | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.007); catalogued as rs1490354818; called by muse, mutect2
- SETD1B | c.4867C>T p.R1623C | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs777899076; called by muse, mutect2, varscan2
- SHISA6 | c.1238C>A p.T413K (on ENST00000409168 / NM_001173461.1; = p.T464K on NM_207386.4) | Missense Mutation (SNP) | VAF 164/359 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0.134); catalogued as rs1210357309, COSV69386931; called by muse, mutect2, varscan2
- SIPA1 | c.2999C>A p.A1000E | Missense Mutation (SNP) | VAF 16/173 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.931); catalogued as COSV58015434, COSV58016109; called by muse, mutect2
- SLC35G6 | c.469T>A p.Y157N | Missense Mutation (SNP) | VAF 253/549 reads (46%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.929); catalogued as rs552862684; called by muse, mutect2, varscan2
- SLC39A12 | c.1663G>T p.D555Y (on ENST00000377369 / NM_001145195.2; = p.D518Y on NM_152725.3) | Missense Mutation (SNP) | VAF 69/267 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66200007; called by muse, mutect2, varscan2
- STAT5B | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 77/402 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.615); catalogued as rs748978416; called by muse, mutect2, varscan2
- STRIP2 | c.2248G>A p.G750R | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776184667, COSV99974041; called by muse, mutect2, varscan2
- TAF1L | c.3079C>T p.R1027C | Missense Mutation (SNP) | VAF 104/402 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778201054, COSV54261755; called by muse, mutect2, varscan2
- TBC1D10A | c.1118A>T p.Q373L | Missense Mutation (SNP) | VAF 53/237 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs1210317537; called by muse, mutect2, varscan2
- TBC1D2B | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.581); catalogued as COSV100317028; called by muse, mutect2, varscan2
- TFIP11 | c.1519T>C p.F507L | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as rs1478021768; called by muse, mutect2
- TRANK1 | c.8030G>T p.R2677L | Missense Mutation (SNP) | VAF 113/243 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.298); catalogued as rs779627377, COSV57162282; called by muse, mutect2, varscan2
- TRIM49 | c.201C>A p.N67K | Missense Mutation (SNP) | VAF 53/832 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs1178827920; called by muse, mutect2
- TTN | c.37986_37987del p.C12662Wfs*12 (on ENST00000591111; = p.C5238Wfs*12 on NM_003319.4) | Frame Shift Del (DEL) | VAF 244/773 reads (32%) | catalogued as rs1114167333; called by pindel, varscan2
- UBR5 | c.396G>A p.W132* | Nonsense Mutation (SNP) | VAF 13/60 reads (22%) | catalogued as COSV55303927; called by muse, mutect2, varscan2
- UMOD | c.1578-2A>T p.X526_splice | Splice Site (SNP) | VAF 27/139 reads (19%) | catalogued as COSV100208484; called by muse, mutect2, varscan2
- UPK3B | c.713G>A p.R238Q (on ENST00000257632; = p.G210S on NM_001347684.2) | Missense Mutation (SNP) | VAF 50/250 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.677); catalogued as rs748232769, COSV99044046; called by muse, mutect2, varscan2
- VPS51 | c.1540del p.E514Rfs*45 | Frame Shift Del (DEL) | VAF 141/419 reads (34%) | catalogued as COSV99659581; called by mutect2, pindel, varscan2
- VWF | c.5273T>C p.V1758A | Missense Mutation (SNP) | VAF 113/415 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1375213244; called by muse, mutect2, varscan2
- WASF3 | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 42/333 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.808); catalogued as rs146594472, COSV58963222; called by muse, mutect2, varscan2
- ZNF234 | c.1173G>T p.Q391H | Missense Mutation (SNP) | VAF 58/375 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.878); catalogued as COSV70603798; called by muse, mutect2, varscan2
- ZNF716 | c.1046A>G p.E349G | Missense Mutation (SNP) | VAF 60/382 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.349); catalogued as rs1408811031; called by muse, mutect2, varscan2
- ZNF786 | c.1446G>T p.Q482H | Missense Mutation (SNP) | VAF 44/234 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs765172914; called by muse, mutect2, varscan2
- ABRA | c.587A>C p.Y196S | Missense Mutation (SNP) | VAF 22/206 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.301); called by muse, mutect2
- AC013489.1 | c.431G>T p.C144F | Missense Mutation (SNP) | VAF 32/295 reads (11%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.8); called by muse, mutect2
- ACTR1A | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 21/177 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM20 | c.388G>T p.G130W | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADAMTS16 | c.2303C>A p.P768H | Missense Mutation (SNP) | VAF 73/212 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS2 | c.2617+1G>T p.X873_splice | Splice Site (SNP) | VAF 54/220 reads (25%) | called by muse, mutect2, varscan2
- ADORA3 | c.332G>T p.R111L | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- ALDH3A1 | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 85/238 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- ANKRD33B | c.366G>A p.R122= | Splice Region (SNP) | VAF 14/26 reads (54%) | called by mutect2, varscan2
- ANKRD6 | c.2032C>A p.Q678K (on ENST00000339746 / NM_001242809.2; = p.Q673K on NM_014942.4) | Missense Mutation (SNP) | VAF 108/211 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- APBA2 | c.370C>A p.H124N | Missense Mutation (SNP) | VAF 138/380 reads (36%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- APEH | c.218G>C p.G73A | Missense Mutation (SNP) | VAF 153/332 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- APOL5 | c.1256C>A p.A419E | Missense Mutation (SNP) | VAF 45/168 reads (27%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- ASRGL1 | c.32G>A p.G11E | Missense Mutation (SNP) | VAF 25/216 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASXL3 | c.2186C>A p.S729Y | Missense Mutation (SNP) | VAF 62/220 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ATP10A | c.1937C>T p.S646F | Missense Mutation (SNP) | VAF 33/350 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.062); called by muse, mutect2
- ATP5F1A | c.1441A>C p.I481L | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- BBS9 | c.1108A>T p.N370Y | Missense Mutation (SNP) | VAF 185/496 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- BCAR1 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- BOD1L1 | c.8963A>T p.E2988V | Missense Mutation (SNP) | VAF 50/188 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CA2 | c.694G>T p.G232W | Missense Mutation (SNP) | VAF 91/323 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- CACNA1G | c.146A>G p.E49G | Missense Mutation (SNP) | VAF 15/230 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2
- CAPZA3 | c.256C>A p.H86N | Missense Mutation (SNP) | VAF 60/240 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CATSPER1 | c.564_565del p.S188Rfs*12 | Frame Shift Del (DEL) | VAF 8/71 reads (11%) | called by mutect2, pindel, varscan2
- CATSPERG | c.3407C>A p.S1136Y | Missense Mutation (SNP) | VAF 54/211 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CBFA2T3 | c.1467G>T p.K489N | Missense Mutation (SNP) | VAF 47/173 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- CCDC102A | c.1306G>A p.V436M | Missense Mutation (SNP) | VAF 74/246 reads (30%) | SIFT tolerated (0.83); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CCDC22 | c.1822G>A p.E608K | Missense Mutation (SNP) | VAF 81/250 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- CCDC3 | c.305C>A p.T102N | Missense Mutation (SNP) | VAF 95/301 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- CCDC85A | c.378G>T p.W126C | Missense Mutation (SNP) | VAF 133/318 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCT5 | c.628A>G p.K210E | Missense Mutation (SNP) | VAF 32/504 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CD1B | c.301G>T p.D101Y | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.539); called by muse, mutect2
- CDK6 | c.590C>A p.A197D | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CELSR2 | c.8471T>C p.L2824P | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- CEP104 | c.2059G>T p.A687S | Missense Mutation (SNP) | VAF 46/258 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- CEP164 | c.3545G>T p.G1182V | Missense Mutation (SNP) | VAF 10/249 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2
- CFHR3 | c.251T>A p.L84H | Missense Mutation (SNP) | VAF 129/443 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- CHD5 | c.5137A>T p.T1713S | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- CHD9 | c.3676G>T p.E1226* | Nonsense Mutation (SNP) | VAF 82/296 reads (28%) | called by muse, mutect2, varscan2
- CHN1 | c.332A>G p.E111G | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, varscan2
- CHST1 | c.794A>G p.Y265C | Missense Mutation (SNP) | VAF 32/239 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- CIB2 | c.428A>T p.E143V | Missense Mutation (SNP) | VAF 91/274 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- CLTCL1 | c.2705G>T p.S902I | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- COL18A1 | c.1248G>T p.Q416H | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- COL2A1 | c.472C>A p.P158T | Missense Mutation (SNP) | VAF 89/260 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL4A2 | c.557C>A p.P186H | Missense Mutation (SNP) | VAF 59/189 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- CROCC | c.934G>T p.E312* | Nonsense Mutation (SNP) | VAF 38/208 reads (18%) | called by muse, mutect2, varscan2
- CSMD1 | c.9692C>A p.S3231Y (on ENST00000520002; = p.S3230Y on NM_033225.6) | Missense Mutation (SNP) | VAF 98/335 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CYFIP2 | c.2836G>T p.G946C (on ENST00000616178 / NM_001291722.2; = p.G921C on NM_014376.4) | Missense Mutation (SNP) | VAF 65/249 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DAOA | c.335A>T p.E112V | Missense Mutation (SNP) | VAF 38/498 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.696); called by muse, mutect2
- DCAF8L2 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 83/256 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- DGKQ | c.1520C>T p.P507L | Missense Mutation (SNP) | VAF 66/183 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- DGLUCY | c.1556C>A p.S519Y | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAJC1 | c.670C>T p.P224S | Missense Mutation (SNP) | VAF 49/435 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAJC16 | c.631G>A p.G211R | Missense Mutation (SNP) | VAF 36/169 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DOCK2 | c.327C>G p.S109R | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.162); called by muse, varscan2
- DSG2 | c.3326A>T p.K1109M | Missense Mutation (SNP) | VAF 147/569 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- DZIP3 | c.484C>A p.L162M | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- EEPD1 | c.38G>T p.R13M | Missense Mutation (SNP) | VAF 11/149 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2
- EGFLAM | c.762C>A p.D254E | Missense Mutation (SNP) | VAF 49/327 reads (15%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- EIF2AK3 | c.1399G>C p.G467R | Missense Mutation (SNP) | VAF 68/174 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ELF3 | c.905_908dup p.K304Lfs*168 | Frame Shift Ins (INS) | VAF 28/125 reads (22%) | called by mutect2, pindel, varscan2
- EPB41L1 | c.370G>C p.D124H | Missense Mutation (SNP) | VAF 93/476 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPHX2 | c.133G>T p.G45* | Nonsense Mutation (SNP) | VAF 42/112 reads (38%) | called by muse, mutect2, varscan2
- EXOC3 | c.2099G>T p.R700L | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FAM83F | c.572C>T p.P191L | Missense Mutation (SNP) | VAF 25/188 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- FAT2 | c.4388del p.P1463Qfs*3 | Frame Shift Del (DEL) | VAF 61/268 reads (23%) | called by mutect2, pindel, varscan2
- FBXL7 | c.370C>A p.Q124K | Missense Mutation (SNP) | VAF 116/337 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FIGNL2 | c.916G>T p.G306C | Missense Mutation (SNP) | VAF 32/246 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- FLG | c.8409G>T p.E2803D | Missense Mutation (SNP) | VAF 228/959 reads (24%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- FMN2 | c.4891C>A p.L1631M | Missense Mutation (SNP) | VAF 16/306 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- FOXS1 | c.718C>A p.P240T | Missense Mutation (SNP) | VAF 48/427 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- FRAS1 | c.10888G>T p.E3630* | Nonsense Mutation (SNP) | VAF 122/368 reads (33%) | called by muse, mutect2, varscan2
- GABRA1 | c.611G>T p.R204L | Missense Mutation (SNP) | VAF 81/323 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GABRB3 | c.1321G>T p.D441Y | Missense Mutation (SNP) | VAF 38/476 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2
- GABRG3 | c.492G>C p.R164S | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- GARNL3 | c.2165G>T p.S722I | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GCNA | c.307G>T p.D103Y | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- GDF3 | c.758T>C p.I253T | Missense Mutation (SNP) | VAF 28/271 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- GK3P | c.866C>A p.T289K | Missense Mutation (SNP) | VAF 106/338 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GLI3 | c.3610C>A p.P1204T | Missense Mutation (SNP) | VAF 31/367 reads (8%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.01); called by muse, mutect2
- GOLGA8H | c.870G>T p.Q290H | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.205); called by mutect2, varscan2
- GPR180 | c.1298G>C p.G433A | Missense Mutation (SNP) | VAF 134/392 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GRIK5 | c.1014C>A p.N338K | Missense Mutation (SNP) | VAF 72/203 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GTPBP10 | c.448G>T p.D150Y | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GTPBP3 | c.487G>T p.D163Y | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GUCY1B1 | c.1788dup p.E597Rfs*22 | Frame Shift Ins (INS) | VAF 37/378 reads (10%) | called by pindel, varscan2
- H3C11 | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.045); called by muse, mutect2
- HGF | c.560C>A p.P187H | Missense Mutation (SNP) | VAF 40/319 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HMCN1 | c.5144C>T p.T1715I | Missense Mutation (SNP) | VAF 26/246 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- HNRNPDL | c.238A>T p.R80W | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.246); called by muse, mutect2
- HNRNPDL | c.236G>T p.R79L | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); called by muse, mutect2
- HOXA3 | c.241C>A p.Q81K | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- HOXA5 | c.346C>A p.H116N | Missense Mutation (SNP) | VAF 29/318 reads (9%) | SIFT tolerated (0.56); PolyPhen benign (0.01); called by muse, mutect2
- HOXA6 | c.130del p.A44Rfs*100 | Frame Shift Del (DEL) | VAF 184/483 reads (38%) | called by mutect2, pindel, varscan2
- HPX | c.510G>T p.W170C | Missense Mutation (SNP) | VAF 22/210 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- HPX | c.509G>A p.W170* | Nonsense Mutation (SNP) | VAF 22/212 reads (10%) | called by muse, mutect2
- HTR1A | c.817G>T p.G273C | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- IFNLR1 | c.227G>T p.G76V | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- IGF2BP2 | c.766C>G p.R256G | Missense Mutation (SNP) | VAF 156/265 reads (59%) | SIFT tolerated (0.18); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- IGHG4 | c.519G>T p.E173D | Missense Mutation (SNP) | VAF 148/1098 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- IGLV7-46 | c.100G>T p.G34* | Nonsense Mutation (SNP) | VAF 22/126 reads (17%) | called by muse, mutect2, varscan2
- IGLV7-46 | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IWS1 | c.2392A>G p.I798V | Missense Mutation (SNP) | VAF 26/285 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.065); called by muse, mutect2
- JDP2 | c.161A>T p.E54V | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- JPH1 | c.453G>T p.M151I | Missense Mutation (SNP) | VAF 77/206 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- JPH3 | c.356A>G p.Y119C | Missense Mutation (SNP) | VAF 58/185 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- KCNA5 | c.746C>G p.A249G | Missense Mutation (SNP) | VAF 72/551 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- KCNH1 | c.1540G>T p.E514* (on ENST00000271751 / NM_172362.3; = p.E487* on NM_002238.4) | Nonsense Mutation (SNP) | VAF 80/287 reads (28%) | called by muse, mutect2, varscan2
- KCNK7 | c.260G>T p.G87V | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.006); called by muse, mutect2
- KCNQ2 | c.2200G>T p.G734W (on ENST00000359125 / NM_172107.4; = p.G706W on NM_004518.6) | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- KIF13B | c.695A>T p.H232L | Missense Mutation (SNP) | VAF 29/278 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KIF17 | c.2221G>T p.V741L | Missense Mutation (SNP) | VAF 70/187 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- KIF3C | c.1123C>A p.P375T | Missense Mutation (SNP) | VAF 135/272 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KLRC1 | c.350G>C p.G117A | Missense Mutation (SNP) | VAF 85/238 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- KMT5C | c.1148G>C p.R383P | Missense Mutation (SNP) | VAF 55/364 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRT75 | c.655G>C p.G219R | Missense Mutation (SNP) | VAF 168/603 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- LAMA1 | c.8491G>T p.D2831Y | Missense Mutation (SNP) | VAF 113/428 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LAMA5 | c.2858G>T p.R953M | Missense Mutation (SNP) | VAF 40/57 reads (70%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LCP1 | c.971G>T p.G324V | Missense Mutation (SNP) | VAF 77/173 reads (45%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- LHX3 | c.1153C>T p.P385S (on ENST00000371748 / NM_178138.6; = p.P390S on NM_014564.5) | Missense Mutation (SNP) | VAF 34/346 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LIG1 | c.1447G>T p.A483S | Missense Mutation (SNP) | VAF 129/407 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- LLCFC1 | c.313G>T p.E105* (on ENST00000458732; = p.E74* on NM_178829.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 97/404 reads (24%) | called by muse, mutect2, varscan2
- LLGL2 | c.1402G>T p.V468L | Missense Mutation (SNP) | VAF 22/207 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- LRRC9 | c.2419C>A p.L807M | Missense Mutation (SNP) | VAF 58/161 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- MAJIN | c.438C>A p.D146E | Missense Mutation (SNP) | VAF 92/229 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MARCHF10 | c.1406C>A p.S469Y | Missense Mutation (SNP) | VAF 57/393 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- MB | c.319-1G>T p.X107_splice | Splice Site (SNP) | VAF 12/48 reads (25%) | called by muse, varscan2
- MC2R | c.749A>T p.Y250F | Missense Mutation (SNP) | VAF 130/530 reads (25%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MCMBP | c.476A>T p.Y159F | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- MOCOS | c.1675G>T p.D559Y | Missense Mutation (SNP) | VAF 40/173 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- MRGBP | c.283A>C p.I95L | Missense Mutation (SNP) | VAF 59/316 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- MUC16 | c.26051A>C p.N8684T | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- MUC16 | c.16022C>T p.S5341L | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYCBP | c.8A>T p.H3L | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MYH13 | c.1495G>T p.E499* | Nonsense Mutation (SNP) | VAF 216/500 reads (43%) | called by muse, mutect2, varscan2
- MYH14 | c.3787G>T p.A1263S | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- MYH7 | c.278T>C p.L93P | Missense Mutation (SNP) | VAF 40/477 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2
- MYH8 | c.5561C>A p.T1854N | Missense Mutation (SNP) | VAF 169/383 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- MYOD1 | c.199del p.A67Rfs*56 | Frame Shift Del (DEL) | VAF 17/121 reads (14%) | called by mutect2, pindel, varscan2
- MYOG | c.160G>T p.G54W | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- NGFR | c.1199C>A p.A400D | Missense Mutation (SNP) | VAF 93/244 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- OR1L1 | c.481G>T p.D161Y (on ENST00000373686; = p.D111Y on NM_001005236.3) | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- OR5K3 | c.395A>G p.Y132C | Missense Mutation (SNP) | VAF 193/329 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OTOG | c.2942C>A p.P981H | Missense Mutation (SNP) | VAF 72/216 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- P2RY8 | c.671A>T p.E224V | Missense Mutation (SNP) | VAF 117/335 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- PARVB | c.163G>T p.G55C | Missense Mutation (SNP) | VAF 26/209 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- PCDH9 | c.3081G>T p.Q1027H | Missense Mutation (SNP) | VAF 71/225 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHA8 | c.46C>A p.L16I | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PDE1C | c.1315T>A p.F439I | Missense Mutation (SNP) | VAF 27/210 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PDHA2 | c.805A>T p.N269Y | Missense Mutation (SNP) | VAF 27/454 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.094); called by muse, mutect2
- PEG3 | c.3124A>T p.T1042S | Missense Mutation (SNP) | VAF 37/290 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- PGM5 | c.185T>C p.M62T | Missense Mutation (SNP) | VAF 50/368 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- PIP | c.332C>A p.A111E | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- PKD1 | c.1934G>T p.R645L | Missense Mutation (SNP) | VAF 43/264 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PKHD1L1 | c.3819G>T p.M1273I | Missense Mutation (SNP) | VAF 39/299 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLA1A | c.67A>C p.S23R | Missense Mutation (SNP) | VAF 54/281 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PLPPR4 | c.932G>T p.G311V | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PNPLA7 | c.119-2A>T p.X40_splice | Splice Site (SNP) | VAF 43/170 reads (25%) | called by muse, mutect2, varscan2
- POTEH | c.546A>T p.R182S | Missense Mutation (SNP) | VAF 72/697 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- POU2F1 | c.1565C>T p.P522L (on ENST00000541643 / NM_001365848.1; = p.P545L on NM_002697.4) | Missense Mutation (SNP) | VAF 80/167 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- PPP1R12C | c.1253G>T p.R418M | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.28); called by muse, mutect2
- PPP1R42 | c.640G>T p.D214Y | Missense Mutation (SNP) | VAF 44/184 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, varscan2
- PRDM10 | c.538A>T p.N180Y | Missense Mutation (SNP) | VAF 232/425 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRICKLE2 | c.617G>A p.G206D (on ENST00000295902; = p.G150D on NM_198859.4) | Missense Mutation (SNP) | VAF 135/269 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PROX1 | c.1189G>T p.G397W | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- PTPRT | c.1039C>A p.L347M | Missense Mutation (SNP) | VAF 138/389 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- PUM1 | c.16G>A p.V6I | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- PWWP3B | c.186A>C p.Q62H | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PYGO1 | c.386A>T p.H129L | Missense Mutation (SNP) | VAF 22/298 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.264); called by muse, mutect2
- RAB9B | c.323A>C p.Y108S | Missense Mutation (SNP) | VAF 124/387 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RASA1 | c.2310dup p.C771Mfs*5 | Frame Shift Ins (INS) | VAF 87/375 reads (23%) | called by mutect2, pindel, varscan2
- RFTN2 | c.1017T>A p.D339E | Missense Mutation (SNP) | VAF 93/212 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RGPD8 | c.3225_3230dup p.W1076_K1077dup | In Frame Ins (INS) | VAF 14/70 reads (20%) | called by mutect2, varscan2
- RPS4X | c.692G>T p.G231V | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- RYR1 | c.11359+1G>A p.X3787_splice | Splice Site (SNP) | VAF 84/287 reads (29%) | called by muse, mutect2, varscan2
- RYR2 | c.10258G>T p.V3420F | Missense Mutation (SNP) | VAF 70/220 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- RYR3 | c.1897A>T p.T633S | Missense Mutation (SNP) | VAF 19/176 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SBSN | c.626G>T p.G209V | Missense Mutation (SNP) | VAF 118/588 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SCN8A | c.2158C>A p.P720T | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, varscan2
- SEPTIN14 | c.479T>C p.V160A | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT tolerated (0.93); PolyPhen benign (0.107); called by muse, mutect2
- SETD2 | c.896G>T p.S299I | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SH2D4A | c.1006G>T p.G336C | Missense Mutation (SNP) | VAF 63/194 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SH3GL3 | c.432G>T p.Q144H | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.963); called by muse, mutect2
- SHBG | c.34C>G p.L12V | Missense Mutation (SNP) | VAF 207/486 reads (43%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SIRPB1 | c.514C>A p.H172N | Missense Mutation (SNP) | VAF 246/658 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- SLC7A13 | c.1180G>T p.V394L | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SOGA1 | c.2777G>A p.G926D | Missense Mutation (SNP) | VAF 20/266 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- SPATC1L | c.667G>T p.V223L (on ENST00000291672 / NM_001142854.2; = p.V69L on NM_032261.5) | Missense Mutation (SNP) | VAF 82/293 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- SPTAN1 | c.4823G>T p.G1608V | Missense Mutation (SNP) | VAF 60/324 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SSTR5 | c.931T>A p.F311I | Missense Mutation (SNP) | VAF 28/202 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- SUPT5H | c.1839G>T p.E613D | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- SUSD2 | c.90C>A p.S30R | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TJP1 | c.3119A>G p.E1040G | Missense Mutation (SNP) | VAF 20/362 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.05); called by muse, mutect2
- TMC1 | c.289G>T p.D97Y | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- TMEM132C | c.1533G>T p.Q511H | Missense Mutation (SNP) | VAF 111/371 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM63C | c.1007C>G p.P336R | Missense Mutation (SNP) | VAF 70/213 reads (33%) | SIFT tolerated (0.86); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TPO | c.842C>A p.A281D | Missense Mutation (SNP) | VAF 73/106 reads (69%) | SIFT tolerated (0.61); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TRAV12-2 | c.50-1G>T p.X17_splice | Splice Site (SNP) | VAF 22/52 reads (42%) | called by muse, mutect2
- TRAV6 | c.110-1G>T p.X37_splice | Splice Site (SNP) | VAF 14/40 reads (35%) | called by muse, mutect2, varscan2
- USH2A | c.6331G>T p.A2111S | Missense Mutation (SNP) | VAF 126/437 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- USP43 | c.3325A>T p.T1109S | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- VAX1 | c.607_610del p.G203Lfs*90 | Frame Shift Del (DEL) | VAF 52/152 reads (34%) | called by mutect2, pindel, varscan2
- VCX | c.82C>A p.P28T | Missense Mutation (SNP) | VAF 68/270 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- VTN | c.776C>A p.A259D | Missense Mutation (SNP) | VAF 96/282 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- VWA5A | c.1411C>A p.L471M | Missense Mutation (SNP) | VAF 24/282 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); called by muse, mutect2
- XKR7 | c.1628G>T p.R543L | Missense Mutation (SNP) | VAF 140/340 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZBED5 | c.1108A>T p.S370C | Missense Mutation (SNP) | VAF 42/462 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.125); called by muse, mutect2
- ZFAND6 | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 26/269 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZFHX2 | c.473T>C p.L158P | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- ZIM2 | c.1073G>T p.C358F | Missense Mutation (SNP) | VAF 29/205 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- ZMYM1 | c.1469G>T p.C490F | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF224 | c.67G>T p.G23W | Missense Mutation (SNP) | VAF 51/272 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ZNF26 | c.499G>T p.A167S | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF382 | c.1259A>G p.K420R | Missense Mutation (SNP) | VAF 31/405 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.011); called by muse, mutect2
- ZNF410 | c.1349G>A p.G450E | Missense Mutation (SNP) | VAF 22/268 reads (8%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.376); called by muse, mutect2
- ZNF418 | c.1873_1874insT p.G625Vfs*6 | Frame Shift Ins (INS) | VAF 117/241 reads (49%) | called by mutect2, pindel, varscan2
- ZNF469 | c.2999A>T p.Q1000L | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- ZNF492 | c.979C>A p.H327N | Missense Mutation (SNP) | VAF 67/283 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- ZNF717 | c.2567G>T p.G856V | Missense Mutation (SNP) | VAF 89/233 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- ZNF729 | c.402G>T p.M134I | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ABCB1 | c.3438G>T p.V1146= | Silent (SNP) | VAF 106/425 reads (25%) | called by muse, mutect2
- ADAM20 | c.390G>T p.G130= | Silent (SNP) | VAF 16/156 reads (10%) | called by muse, mutect2
- ADAMTS20 | c.2364T>C p.N788= | Silent (SNP) | VAF 48/260 reads (18%) | catalogued as COSV101166349; called by muse, mutect2, varscan2
- ADGRB2 | c.3498C>A p.L1166= | Silent (SNP) | VAF 49/192 reads (26%) | called by muse, mutect2, varscan2
- AGPAT4 | c.273C>T p.I91= | Silent (SNP) | VAF 84/192 reads (44%) | catalogued as rs758554938, COSV57242742, COSV57247377; called by muse, mutect2, varscan2
- ASCL2 | c.207C>T p.G69= | Silent (SNP) | VAF 19/243 reads (8%) | catalogued as rs1335927576; called by muse, mutect2
- ASMTL | c.297G>A p.E99= | Silent (SNP) | VAF 63/228 reads (28%) | catalogued as rs1435339474; called by muse, mutect2, varscan2
- BRWD1 | c.4440C>T p.T1480= | Silent (SNP) | VAF 53/157 reads (34%) | called by muse, mutect2, varscan2
- BTNL9 | c.345C>T p.S115= | Silent (SNP) | VAF 62/213 reads (29%) | catalogued as rs745393127; called by muse, mutect2, varscan2
- CABIN1 | c.5181C>T p.L1727= | Silent (SNP) | VAF 76/341 reads (22%) | called by muse, mutect2, varscan2
- CD82 | c.672G>C p.L224= | Silent (SNP) | VAF 75/210 reads (36%) | catalogued as COSV57037764; called by muse, mutect2, varscan2
- CFHR4 | c.984C>A p.V328= (on ENST00000367416 / NM_001201551.2; = p.V329= on NM_001201550.3) | Silent (SNP) | VAF 10/124 reads (8%) | called by muse, mutect2
- CNGA3 | c.1116C>A p.P372= | Silent (SNP) | VAF 35/61 reads (57%) | catalogued as COSV55622725; called by muse, mutect2, varscan2
- COL12A1 | c.8871A>T p.G2957= | Silent (SNP) | VAF 67/726 reads (9%) | called by muse, mutect2
- COL22A1 | c.2496G>A p.L832= | Silent (SNP) | VAF 69/286 reads (24%) | catalogued as rs192785367, COSV57346371; called by muse, mutect2, varscan2
- COL4A2 | c.444G>T p.G148= | Silent (SNP) | VAF 57/125 reads (46%) | called by muse, mutect2, varscan2
- CPPED1 | c.267C>T p.G89= | Silent (SNP) | VAF 14/88 reads (16%) | catalogued as rs764661639, COSV55495612; called by muse, mutect2, varscan2
- CYFIP2 | c.2256A>T p.R752= (on ENST00000616178 / NM_001291722.2; = p.R727= on NM_014376.4) | Silent (SNP) | VAF 15/135 reads (11%) | called by muse, mutect2, varscan2
- DAPK3 | c.1221C>T p.S407= | Silent (SNP) | VAF 58/169 reads (34%) | catalogued as rs771292370; called by muse, mutect2, varscan2
- DCBLD1 | c.1392G>T p.V464= | Silent (SNP) | VAF 121/320 reads (38%) | catalogued as COSV51641353, COSV51643761; called by muse, mutect2, varscan2
- DCDC1 | c.3369A>T p.S1123= (on ENST00000597505 / NM_001367979.1; = p.S230= on NM_020869.3) | Silent (SNP) | VAF 18/269 reads (7%) | called by muse, mutect2
- EFCAB3 | c.1233C>G p.S411= | Silent (SNP) | VAF 18/140 reads (13%) | catalogued as COSV59500203; called by muse, mutect2, varscan2
- FAT3 | c.6654C>A p.I2218= | Silent (SNP) | VAF 14/168 reads (8%) | catalogued as COSV53095547; called by muse, mutect2
- FREM2 | c.4536C>T p.T1512= | Silent (SNP) | VAF 32/342 reads (9%) | catalogued as rs771382493; called by muse, mutect2
- GFRA4 | c.697C>A p.R233= (on ENST00000319242 / NM_145762.3; = p.R203= on NM_022139.4) | Silent (SNP) | VAF 48/284 reads (17%) | called by muse, varscan2
- GNAT3 | c.552C>A p.I184= | Silent (SNP) | VAF 26/217 reads (12%) | catalogued as COSV101242417; called by muse, mutect2, varscan2
- HAPLN2 | c.726C>A p.T242= | Silent (SNP) | VAF 22/59 reads (37%) | called by muse, mutect2, varscan2
- HRNR | c.3171A>G p.S1057= | Silent (SNP) | VAF 566/2361 reads (24%) | called by muse, mutect2, varscan2
- IFI16 | c.1038G>T p.V346= | Silent (SNP) | VAF 150/355 reads (42%) | called by muse, mutect2, varscan2
- IFT140 | c.3744C>T p.I1248= | Silent (SNP) | VAF 40/349 reads (11%) | catalogued as COSV100794235, COSV63699249; called by muse, mutect2, varscan2
- IL1A | c.585C>A p.A195= | Silent (SNP) | VAF 78/212 reads (37%) | called by muse, mutect2, varscan2
- ITGA2B | c.2562C>T p.G854= | Silent (SNP) | VAF 150/383 reads (39%) | called by muse, mutect2, varscan2
- KCNH4 | c.918C>A p.A306= | Silent (SNP) | VAF 141/448 reads (31%) | called by muse, mutect2, varscan2
- KCNJ4 | c.873G>A p.E291= | Silent (SNP) | VAF 48/188 reads (26%) | called by muse, mutect2, varscan2
- KCNQ2 | c.2199G>T p.V733= (on ENST00000359125 / NM_172107.4; = p.V705= on NM_004518.6) | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV60555966; called by muse, mutect2, varscan2
- KLHL34 | c.498G>C p.A166= | Silent (SNP) | VAF 31/85 reads (36%) | called by muse, mutect2, varscan2
- KRT20 | c.867G>T p.L289= | Silent (SNP) | VAF 51/365 reads (14%) | catalogued as COSV51425756; called by muse, mutect2, varscan2
- KRT38 | c.597G>T p.L199= | Silent (SNP) | VAF 82/201 reads (41%) | called by muse, mutect2, varscan2
- KRTAP16-1 | c.1503C>A p.T501= | Silent (SNP) | VAF 9/48 reads (19%) | called by muse, mutect2, varscan2
- L3MBTL4 | c.1081C>T p.L361= | Silent (SNP) | VAF 56/180 reads (31%) | catalogued as COSV53124515; called by muse, mutect2, varscan2
- LAMA1 | c.8238C>T p.F2746= | Silent (SNP) | VAF 22/392 reads (6%) | catalogued as rs150815120; called by muse, mutect2
- LRP1 | c.8550C>T p.S2850= | Silent (SNP) | VAF 83/260 reads (32%) | called by muse, mutect2, varscan2
- LRRFIP1 | c.1269G>T p.V423= (on ENST00000392000 / NM_001137552.2; = p.V399= on NM_004735.4) | Silent (SNP) | VAF 73/135 reads (54%) | called by muse, mutect2, varscan2
- LSM7 | c.213G>T p.L71= | Silent (SNP) | VAF 27/65 reads (42%) | called by muse, mutect2, varscan2
- LTBP3 | c.2436C>T p.L812= | Silent (SNP) | VAF 53/535 reads (10%) | called by muse, mutect2, varscan2
- MAGEB5 | c.666C>A p.A222= | Silent (SNP) | VAF 112/333 reads (34%) | called by muse, mutect2, varscan2
- MGAM2 | c.4389C>A p.T1463= | Silent (SNP) | VAF 28/247 reads (11%) | called by muse, mutect2, varscan2
- MMP17 | c.816C>A p.G272= | Silent (SNP) | VAF 26/266 reads (10%) | called by muse, mutect2
- MTR | c.1743C>T p.S581= | Silent (SNP) | VAF 26/358 reads (7%) | catalogued as rs758784869; ClinVar: likely benign; called by muse, mutect2
- MUC16 | c.36276G>T p.R12092= | Silent (SNP) | VAF 56/185 reads (30%) | catalogued as rs766904193; called by muse, mutect2, varscan2
- NAIF1 | c.645G>T p.P215= | Silent (SNP) | VAF 76/361 reads (21%) | called by muse, mutect2, varscan2
- NDN | c.612C>A p.G204= | Silent (SNP) | VAF 14/166 reads (8%) | catalogued as rs748616399, COSV100086575, COSV59359816; called by muse, mutect2
- NES | c.939G>C p.L313= | Silent (SNP) | VAF 37/97 reads (38%) | called by muse, mutect2, varscan2
- NLRP8 | c.1272C>G p.T424= | Silent (SNP) | VAF 99/300 reads (33%) | catalogued as rs762090854; called by muse, mutect2, varscan2
- OR11L1 | c.603C>A p.I201= | Silent (SNP) | VAF 110/321 reads (34%) | called by muse, mutect2, varscan2
- OR8K3 | c.600G>T p.L200= | Silent (SNP) | VAF 13/131 reads (10%) | called by muse, mutect2, varscan2
- P3H3 | c.1398G>T p.R466= | Silent (SNP) | VAF 21/270 reads (8%) | called by muse, mutect2
- PDE6A | c.2217T>A p.A739= | Silent (SNP) | VAF 89/271 reads (33%) | called by muse, mutect2, varscan2
- PIK3R5 | c.588G>T p.L196= | Silent (SNP) | VAF 151/305 reads (50%) | called by muse, mutect2, varscan2
- PXDNL | c.597C>A p.A199= | Silent (SNP) | VAF 83/251 reads (33%) | called by muse, mutect2, varscan2
- RASAL3 | c.3000C>A p.P1000= | Silent (SNP) | VAF 19/67 reads (28%) | called by muse, mutect2, varscan2
- RRBP1 | c.1983G>T p.V661= (on ENST00000377813 / NM_001365613.2; = p.V228= on NM_004587.3) | Silent (SNP) | VAF 36/338 reads (11%) | called by muse, varscan2
- RSPH10B2 | c.234G>T p.L78= | Silent (SNP) | VAF 103/267 reads (39%) | catalogued as rs781042977; called by muse, mutect2, varscan2
- SCN4A | c.2421C>A p.A807= | Silent (SNP) | VAF 10/58 reads (17%) | called by muse, mutect2, varscan2
- SEMA6C | c.2703C>T p.D901= | Silent (SNP) | VAF 112/242 reads (46%) | called by muse, mutect2, varscan2
- SHISA6 | c.210G>T p.A70= | Silent (SNP) | VAF 17/21 reads (81%) | catalogued as rs914467106; called by muse, mutect2, varscan2
- SIPA1L2 | c.3327C>T p.F1109= | Silent (SNP) | VAF 55/578 reads (10%) | catalogued as rs200409966; called by muse, mutect2
- SLC6A17 | c.426C>A p.I142= | Silent (SNP) | VAF 41/168 reads (24%) | called by muse, mutect2, varscan2
- SLX4 | c.300C>A p.T100= | Silent (SNP) | VAF 31/199 reads (16%) | called by muse, mutect2, varscan2
- SON | c.2040G>A p.A680= | Silent (SNP) | VAF 32/386 reads (8%) | catalogued as rs973496828; called by muse, mutect2
- SRRM2 | c.3807A>G p.E1269= | Silent (SNP) | VAF 23/156 reads (15%) | called by muse, mutect2, varscan2
- SSU72 | c.240G>T p.G80= | Silent (SNP) | VAF 22/75 reads (29%) | called by muse, mutect2, varscan2
- SUPT20HL2 | c.696C>T p.T232= | Silent (SNP) | VAF 106/302 reads (35%) | called by muse, mutect2, varscan2
- SYCP2 | c.3267A>T p.L1089= | Silent (SNP) | VAF 121/304 reads (40%) | called by muse, mutect2, varscan2
- SYNDIG1 | c.360G>A p.S120= | Silent (SNP) | VAF 115/748 reads (15%) | catalogued as rs149754312; called by muse, mutect2, varscan2
- TMPRSS7 | c.102A>G p.R34= | Silent (SNP) | VAF 196/355 reads (55%) | called by muse, mutect2, varscan2
- TRANK1 | c.5988G>C p.L1996= | Silent (SNP) | VAF 85/180 reads (47%) | called by muse, mutect2, varscan2
- TRDN | c.129G>T p.T43= | Silent (SNP) | VAF 145/396 reads (37%) | called by muse, mutect2, varscan2
- TRIO | c.2349G>A p.E783= | Silent (SNP) | VAF 53/319 reads (17%) | called by muse, mutect2, varscan2
- UNC80 | c.6432C>A p.L2144= | Silent (SNP) | VAF 55/117 reads (47%) | called by muse, mutect2
- USH2A | c.5331G>T p.R1777= | Silent (SNP) | VAF 93/243 reads (38%) | catalogued as rs771621501; called by muse, mutect2, varscan2
- WNT1 | c.474C>A p.R158= | Silent (SNP) | VAF 31/220 reads (14%) | catalogued as rs770842572; called by muse, mutect2, varscan2
- ZBTB38 | c.2676C>T p.C892= | Silent (SNP) | VAF 10/146 reads (7%) | called by muse, mutect2
- ZMIZ1 | c.2607G>T p.P869= | Silent (SNP) | VAF 59/182 reads (32%) | catalogued as rs367668686; called by muse, mutect2, varscan2
- ZNF28 | c.1101G>T p.L367= | Silent (SNP) | VAF 155/420 reads (37%) | called by muse, mutect2, varscan2
- ZNF98 | c.1119T>A p.S373= | Silent (SNP) | VAF 62/257 reads (24%) | called by muse, mutect2, varscan2
- ADAD2 | c.734-27G>T | Intron (SNP) | VAF 22/87 reads (25%) | called by muse, mutect2, varscan2
- ADAD2 | c.734-26G>T | Intron (SNP) | VAF 22/87 reads (25%) | called by muse, mutect2, varscan2
- ANK1 | c.5619+207C>T | Intron (SNP) | VAF 30/282 reads (11%) | called by muse, mutect2, varscan2
- B3GALT5-AS1 | n.642C>A | RNA (SNP) | VAF 42/361 reads (12%) | called by muse, varscan2
- BIN1 | c.*6G>T | 3'UTR (SNP) | VAF 158/295 reads (54%) | catalogued as COSV99388660; called by muse, mutect2, varscan2
- BRCA1 | c.*273T>G | 3'UTR (SNP) | VAF 33/135 reads (24%) | called by muse, mutect2, varscan2
- C11orf96 | chr11:43943495 C>G | 3'Flank (SNP) | VAF 19/251 reads (8%) | called by muse, mutect2
- CCDC22 | c.-21C>T | 5'UTR (SNP) | VAF 12/274 reads (4%) | called by muse, mutect2
- CPLANE1 | c.*3676G>A | 3'UTR (SNP) | VAF 38/242 reads (16%) | called by muse, mutect2, varscan2
- CPT1C | c.879+13C>G | Intron (SNP) | VAF 55/132 reads (42%) | called by muse, mutect2, varscan2
- CYLC1 | c.-10G>T | 5'UTR (SNP) | VAF 88/275 reads (32%) | catalogued as COSV61410232; called by muse, mutect2, varscan2
- DENND5B | c.128-4525G>T | Intron (SNP) | VAF 9/64 reads (14%) | called by muse, mutect2
- DENND5B | c.128-4526G>T | Intron (SNP) | VAF 9/65 reads (14%) | called by muse, mutect2
- DHCR24 | c.*29G>T | 3'UTR (SNP) | VAF 36/111 reads (32%) | catalogued as COSV100987809; called by muse, mutect2, varscan2
- DNAJA4 | c.132+678T>C | Intron (SNP) | VAF 38/436 reads (9%) | catalogued as rs1318216491; called by muse, mutect2
- DNMT1 | c.4245+21_4245+22dup | Intron (INS) | VAF 19/200 reads (10%) | called by mutect2, pindel, varscan2
- DUX4L8 | n.706C>T | RNA (SNP) | VAF 52/245 reads (21%) | catalogued as rs782032535; called by muse, varscan2
- ERLIN2 | c.425-1998G>T | Intron (SNP) | VAF 48/506 reads (9%) | called by muse, mutect2
- ETDB | chrX:135123399 G>A | 5'Flank (SNP) | VAF 90/310 reads (29%) | catalogued as rs1455913104; called by muse, mutect2, varscan2
- FCN1 | c.*206C>A | 3'UTR (SNP) | VAF 12/117 reads (10%) | called by muse, mutect2, varscan2
- GIPR | c.925-42G>T | Intron (SNP) | VAF 64/396 reads (16%) | called by muse, mutect2, varscan2
- HERC2 | c.13273-231G>C | Intron (SNP) | VAF 229/694 reads (33%) | called by muse, mutect2, varscan2
- IGKV1OR22-5 | n.144G>T | RNA (SNP) | VAF 44/797 reads (6%) | called by muse, mutect2
- IPO8 | c.640-338G>T | Intron (SNP) | VAF 14/215 reads (7%) | called by muse, mutect2
- KATNB1 | c.-12G>T | 5'UTR (SNP) | VAF 41/256 reads (16%) | called by muse, mutect2, varscan2
- KCNT1 | c.377+1340C>A | Intron (SNP) | VAF 36/285 reads (13%) | called by muse, mutect2, varscan2
- KIF28P | n.2619C>A | RNA (SNP) | VAF 64/225 reads (28%) | called by muse, mutect2
- KLRK1 | c.-27C>A | 5'UTR (SNP) | VAF 28/212 reads (13%) | catalogued as rs113385206; called by muse, varscan2
- LILRB1 | c.1801-427G>T | Intron (SNP) | VAF 22/118 reads (19%) | called by muse, mutect2, varscan2
- LRMDA | c.-73C>T | 5'UTR (SNP) | VAF 6/16 reads (38%) | called by mutect2, varscan2
- MBNL2 | c.994+1358C>T | Intron (SNP) | VAF 70/174 reads (40%) | catalogued as rs1360364352, COSV59121747; called by muse, mutect2, varscan2
- MIRLET7BHG | n.309-3695G>T | Intron (SNP) | VAF 52/485 reads (11%) | called by muse, mutect2
- MS4A1 | c.280-475C>A | Intron (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2, varscan2
- OTUD6B | c.316-1668T>G | Intron (SNP) | VAF 27/225 reads (12%) | called by muse, mutect2, varscan2
- OTX1 | c.-25G>T | 5'UTR (SNP) | VAF 108/203 reads (53%) | called by muse, mutect2, varscan2
- PAX5 | c.781-7453C>A | Intron (SNP) | VAF 26/210 reads (12%) | catalogued as COSV63908545; called by muse, mutect2, varscan2
- PTPRK | c.2841+204G>C | Intron (SNP) | VAF 132/344 reads (38%) | catalogued as rs753884047; called by muse, varscan2
- RABGAP1L | c.2212-11425C>T | Intron (SNP) | VAF 12/272 reads (4%) | catalogued as rs1195157995; called by muse, mutect2
- RNY4P30 | chr13:49892746 C>A | 5'Flank (SNP) | VAF 148/447 reads (33%) | called by muse, varscan2
- SLC12A3 | c.*4C>T | 3'UTR (SNP) | VAF 18/249 reads (7%) | catalogued as COSV99344060; called by muse, mutect2
- SNX29P2 | n.877C>G | RNA (SNP) | VAF 34/332 reads (10%) | called by muse, mutect2, varscan2
- SRCIN1 | c.22+1099C>A | Intron (SNP) | VAF 32/185 reads (17%) | called by muse, mutect2, varscan2
- STRA6 | c.865+39C>A | Intron (SNP) | VAF 127/358 reads (35%) | catalogued as COSV60584905; called by muse, mutect2, varscan2
- TMEM213 | c.*13G>T | 3'UTR (SNP) | VAF 48/165 reads (29%) | called by muse, mutect2, varscan2
- UBTFL2 | n.203G>C | RNA (SNP) | VAF 47/185 reads (25%) | called by muse, mutect2, varscan2
- VSIG10 | c.1331-32G>A | Intron (SNP) | VAF 21/67 reads (31%) | called by muse, mutect2, varscan2
- WNT16 | chr7:121325418 G>A | 5'Flank (SNP) | VAF 21/168 reads (13%) | catalogued as rs1371402202; called by muse, mutect2, varscan2
- WT1 | c.965+1047G>T | Intron (SNP) | VAF 170/423 reads (40%) | called by muse, mutect2, varscan2
- ZFHX4 | c.3325+3714C>T | Intron (SNP) | VAF 65/202 reads (32%) | catalogued as rs1033391439; called by muse, mutect2, varscan2
- ZMAT4 | c.103-18987G>T | Intron (SNP) | VAF 24/213 reads (11%) | called by muse, varscan2
